Surgical pathology report (de-identified scan), TCGA case TCGA-OR-A5JX, project TCGA-ACC (Adrenocortical Carcinoma), tissue source site University of Michigan, specimen TCGA-OR-A5JX-01A (Primary Tumor).

[page 1 of 2]
PREVIOUS DIAGNOSIS INQUIRY

PAGE #: 1
SEX: M
ADM DATE:

OPER DATE:

PROCEDURE: SPHS

History: Left adrenal tumor. Hypertension, current smoker.
Source of Specimen: Mesenteric implant. Left adrenal cancer.
Operative Procedure/Tissue Submitted: Left adrenalectomy.

PROCEDURE: SPGD

1. "Mesenteric implant." A 0.1 cm bit. Frozen section control.
2. "Left renal vein lymph node." A 1.5 cm lymph node with a fleshy cut surface. Bisected. Frozen section control.
3. "Left adrenal gland. One long stitch medial, two long stitches anterior, two short stitches adrenal vein." Received in formalin in a large container is a 10.5 x 10.5 x 6.0 cm, oriented adrenal gland weighing 445 gm (untrimmed weight). The specimen is inked as follows: Anterior - yellow, posterior - black, superior - blue, inferior - green, medial - red and lateral - orange. Specimen is sectioned to reveal a 10.0 x 8.0 x 6.0 cm, encapsulated mass. The tumor is friable and largely necrotic and grossly appears to abut all margins.
- 3A. Renal vein margin and tumor just distal.
- 3B. Tumor to medial margin.
- 3C. Tumor to anterior margin.
- 3D. Tumor to posterior.
- 3E. Tumor to inferior.
- 3F. Tumor to lateral and tumor to superior.
- 3G-H. Additional representative sections of central tumor.
- 3I. Normal adrenal gland.

3 ADD 1-10. Tumor.

4. "Retroperitoneal fat." Received in formalin in a small container is a 7 x 6 x 1.5 cm irregular portion of hemorrhagic yellow adipose that is partially encapsulated. Cut surface is a yellow lobular adipose with no lesions identified.

4A-C. Adipose.

5. "Left perirenal tissue." Received in formalin in a small container is a 5 x 5 x 2 cm aggregate of pink-yellow fibroadipose tissue that is partially encapsulated. Focal areas of hemorrhage are identified. Cut surface is unremarkable.

5A-C. Adipose.

FROZEN SECTION REPORT

1. Inflamed fibrotic tissue, favor fat necrosis.
2. Negative for carcinoma.

_____ have reviewed and interpreted the frozen section material at the time it was requested.

ICD-3
Carcinoma, adrenal cortical
Site: Adrenal Gland, cortex
Q40 1/35/13
8376/3
0740

[page 2 of 2]
PREVIOUS DIAGNOSIS INQUIRY

REPORT DATE:

PAGE #: 2

BIRTHDATE:

PAT TYPE:

SEX: M

ADM DATE:

OPER DATE:

Permanent sections confirm frozen section report.

PROCEDURE: SPMI

ADRENOCORTICAL CARCINOMA

=====

Tumor Size: 10 x 8 x 6 cm

Tumor Weight: 445 gm

Capsular Invasion: Yes

Vascular Invasion: Yes (adrenal vein)

Surgical Margins: Negative

Necrosis: Yes, focal

Mitotic Rate: 5 mitoses / 50 hpf

Grade: Low

Extra-adrenal Extension: Yes, adrenal vein

Stage: III

Immunohistochemistry results:

alpha-inhibin Positive
Melan-A Positive

PROCEDURE: SPDX

3. Left adrenal gland, resection: Adrenocortical carcinoma, low-grade by mitotic activity, with invasion of adrenal vein. See Template. free.

1. Mesenteric implant, excision: Benign mesenteric cyst with chronic inflammation, negative for neoplasm.

2. Left renal vein lymph node, resection: One lymph node, negative for neoplasm.

4-5. Retroperitoneal fat, left perirenal tissue, resection: Benign fibroadipose tissue, negative for neoplasm.

Case is (re)traced		
Reviewer Initials	QUALIFIED / L. SQUARIEL	12/13

Source: NCI Genomic Data Commons file 98cd93f2-b0a2-4e21-ad1e-6f89d1399319 (TCGA-OR-A5JX.6F548B5E-C4A2-46C7-8B56-7DD037CC49B5.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).